Somatic mutation profile of tumor specimen TCGA-AP-A5FX-01A (aliquot TCGA-AP-A5FX-01A-11D-A27P-09) from TCGA case TCGA-AP-A5FX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 68.6 years (25,063 days).
Specimen TCGA-AP-A5FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7316c972-a86a-41a6-8a24-f43d9f93aad7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A5FX-10A (Blood Derived Normal), aliquot TCGA-AP-A5FX-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/583d9727-1eeb-407f-9c0a-6734fea87e48

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100686567, COSV104419916; called by muse, mutect2, varscan2
- ALX1 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV100374501; called by muse, mutect2, varscan2
- BIRC6 | c.12168A>G p.I4056M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV66042951; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4040C>G p.S1347* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100863660, COSV63245337; called by muse, mutect2, varscan2
- C9orf72 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV101186530; called by muse, mutect2
- CASZ1 | c.1531C>G p.H511D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100681716; called by muse, mutect2, varscan2
- COL4A1 | c.4966C>T p.R1656C | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs377350886; called by muse, mutect2, varscan2
- CSRP2 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.152); catalogued as COSV100222771; called by muse, mutect2, varscan2
- DLGAP1 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100229910, COSV100232387; called by muse, mutect2, varscan2
- FAM47A | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776894713, COSV60499165, COSV60499902; called by muse, mutect2, varscan2
- H1-2 | c.230_232del p.N77del | In Frame Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs774779034; called by pindel, varscan2
- IGFBP1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as rs1463639023, COSV99298783; called by muse, mutect2, varscan2
- KCNN3 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.15); catalogued as COSV99678726; called by muse, mutect2, varscan2
- LY75 | c.3946A>G p.I1316V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99716662; called by muse, mutect2, varscan2
- MLEC | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57329752; called by muse, mutect2, varscan2
- MTUS2 | c.2518G>A p.G840R | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200465559, COSV99079522; called by muse, mutect2, varscan2
- OR2AG1 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs1394113888, COSV100264900; called by muse, mutect2, varscan2
- ORMDL1 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100360638; called by muse, mutect2, varscan2
- PLEKHA4 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371994811; called by muse, mutect2, varscan2
- PREPL | c.1040C>A p.T347K | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99576291; called by muse, mutect2, varscan2
- RAD51AP2 | c.3457G>A p.G1153R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.017); catalogued as rs778982226, COSV67587627; called by muse, mutect2, varscan2
- RASAL3 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV99653441; called by muse, mutect2, varscan2
- SFTPB | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs370715446; called by muse, mutect2
- SLC12A2 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs373411636, COSV52477470; called by muse, mutect2, varscan2
- SLC6A3 | c.286+1G>A p.X96_splice | Splice Site (SNP) | VAF 32/66 reads (48%) | catalogued as COSV99548587; called by muse, mutect2, varscan2
- SSR2 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs773535812, COSV99828631; called by muse, mutect2, varscan2
- TACC2 | c.5905C>T p.P1969S (on ENST00000334433; = p.P47S on NM_006997.4) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1384973683, COSV99587302; called by muse, mutect2, varscan2
- TRIM68 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1402163841, COSV100331759; called by muse, mutect2, varscan2
- ZNF543 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.071); catalogued as COSV58626493; called by muse, mutect2, varscan2
- ZSCAN10 | c.602C>T p.A201V (on ENST00000252463; = p.A256V on NM_032805.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs758487406, COSV99374168; called by muse, mutect2, varscan2
- TPTE | c.1391T>A p.I464N (on ENST00000618007 / NM_199261.4; = p.I446N on NM_199259.4) | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- C7orf57 | c.156C>T p.S52= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1191220681, COSV100817300; called by muse, mutect2, varscan2
- CCDC171 | c.3276C>T p.S1092= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs779360486, COSV52650827; called by muse, mutect2, varscan2
- FBXO46 | c.657C>T p.S219= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs756006396, COSV100480265; called by muse, mutect2, varscan2
- FCGBP | c.6555C>T p.L2185= | Silent (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- FLT3LG | c.210C>T p.C70= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs776638815, COSV99201327; called by muse, mutect2, varscan2
- HSPA6 | c.831C>G p.S277= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100554204; called by muse, mutect2, varscan2
- MFSD13A | c.897C>T p.I299= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99487952; called by muse, mutect2, varscan2
- PPFIA2 | c.2712C>T p.V904= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100334352; called by muse, mutect2, varscan2
- PRDM9 | c.420G>T p.L140= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99690700, COSV99690727; called by muse, mutect2, varscan2
- SMC5 | c.3171G>A p.L1057= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV63192951; called by muse, mutect2, varscan2
